TCGA case TCGA-EX-A69M — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1e4d7755-b971-4c6e-a2b9-dd83d92bc4c9

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Dead; Days to death: 253 days; Cause of death: Cancer Related.

Diagnoses (3)
1. Squamous cell carcinoma, large cell, nonkeratinizing, NOS (the primary disease): ICD-O-3 morphology code: 8072/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 62.7 years (22,917 days); Year of diagnosis: 2012; Method of diagnosis: Cytology; AJCC pathologic T: T1b2; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IB2; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 11.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Pharmaceutical Therapy, NOS, postoperative (reason: Not Done per Treating Physician's Discretion); adjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, postoperative (reason: Not Done per Treating Physician's Discretion).
2. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Mouth, NOS; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 57.8 years (21,112 days); Days to diagnosis: -1,805 days (-4.9 years); AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I.
   Treatment given: Treatment type: Biopsy, Excisional; Days to treatment start: -1,756 days (-4.8 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Subsequent primary of the lung (histology not recorded by GDC). Age at diagnosis: 63.0 years (22,994 days); Days to diagnosis: 77 days; Prior treatment: Yes.

Follow-up (9 entries)
- Day 18 (preoperative): Days to imaging: 18 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 18 (preoperative): Days to imaging: 18 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 18 (preoperative): Days to imaging: 18 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 18 (preoperative): Days to imaging: 18 days; Imaging type: PET; Imaging result: Positive; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 18 (preoperative): Days to imaging: 18 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 18 (preoperative): Days to imaging: 18 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Days to follow up: 186 days; Disease response: Tumor Free.
- Days to follow up: 253 days; Disease response: Tumor Free.
- ECOG performance status: 1; Timepoint: Preoperative.

Molecular and laboratory tests
- Human Papillomavirus (IHC): Positive [Hpv strain: HPV16].
- Human Papillomavirus (IHC): Positive [Hpv strain: HPV63].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 58 kg; Height: 158 cm; BMI: 23.2.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 3; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Comorbidities: Human Papillomavirus Infection; Risk factors: Human Papillomavirus Infection.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Ectopic Pregnancy.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking quit year: 2012.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EX-A69M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 690 mg.
  Slide TCGA-EX-A69M-01A-01-TS1: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
- Sample TCGA-EX-A69M-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EX-A69M-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 3; Pregnancies count ectopic: 1; Total pregnancy count: 4; Tobacco smoking history indicator: 4; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymph nodes examined: Yes; HPV types other: HPV 63; HPV typing method other: Immunostain; New tumor event diagnosis indicator: Yes.
- Fdg or ct pet performed outcomes: Fedpet or ct results: Bladder Absent; Fedpet or ct results: Extra-Pelvic Metastatic Disease Present; Fedpet or ct results: Parametrium Absent; Fedpet or ct results: Paraaortic Nodes Absent; Fedpet or ct results: Pelvic Nodes Absent; Fedpet or ct results: Supraclavicular Absent.
- Human papillomavirus types: HPV types positive: HPV 16; HPV types positive: Other HPV type(s).
- Treatment, Radiation therapy info: Radiation treatment reason not completed: Not done per treating physician discretion.
- Treatment, Concurrent prescription treatment info: Chemo concurrent reason not given: Not done per treating physicians discretion.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site: Lung; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Cause of death other: Lung Cancer; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: Yes.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Oral cavity; Other malignancy histological type: Squamous Cell Carcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Other malignancy surgery type: Excisional biopsy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 253 days; disease-specific survival: no event (censored), 253 days; disease-free interval: no event (censored), 253 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 77 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EX-A69M-01A-11D-A32H-01): tumor purity 0.69, ploidy 2.11, whole-genome doublings 0.
